Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A23N, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A23N-01A (Primary Tumor).

[page 1 of 2]
Sex: Female
D.O.B.:
MRN #:
Ref Phys:

SPECIMEN INFORMATION

Collected:

Accession:

Received:

Acct / Reg

Reported:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Portion of omentum, excision:

Metastatic high grade adenocarcinoma, diffusely infiltrative.
Frozen section diagnosis confirmed.

B. Omentum, excision:

Diffusely infiltrative high grade adenocarcinoma.

C. Uterus, right adnexa, hysterectomy with right salpingoophorectomy:

Tumor Characteristics:

1. Histologic type: ~~Endometrial~~ carcinoma
2. Histologic grade: 3.
3. Tumor site: Endometrium
4. Tumor size: Tumor microscopic in its originating source measuring approximately 1.0 cm in lateral dimension.
5. Myometrial invasion: Tumor focally extends 0.3 cm into a 1.1 cm thick myometrium.
6. Involvement of cervix: Cervix not removed.
7. Extent of involvement of other organs: Tumor extends into the right ovary as well as within the parametrial tissue as well as extensively along the uterine serosa.
8. Lymphovascular space invasion: Not definitively identified.

Surgical Margin Status:

Tumor does not definitively extend to margins of resection, however, is metastatic multifocally.

Lymph Node Status:

No lymph nodes removed.

Other:

1. Other significant findings:

- a. Background endometrium with predominantly atrophic features.
- b. Right fallopian tube without significant pathologic abnormality.

2. pTNM stage: pT3a NX (FIGO IIIA).

HIFAA Discrepancy		☒

ICD-O-3

Carcinoma, serous, NOS 8441/3
Site: Endometrium C54.1

4/19/11

Electronic Signature:

COMMENTS:

Appropriately controlled immunohistochemical stains for WT-1 and P53 performed on blocks C10 and C13 show positive staining for p53 with no to only focal nuclear staining for WT1. This, along with patient age and background atrophic endometrium are consistent with a serous carcinoma of endometrial origin.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Adenocarcinoma on Pap, thickened endometrium. Biopsy not possible - cervical stenosis

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Portion of omentum with frozen section
- B. Omentum
- C. Uterus, right tube and ovary

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three containers labeled with the patient's name,

[page 2 of 2]
Container A is additionally labeled "portion of omentum" and contains a 10.0 x 5.0 x 3.0 cm, yellow-tan, finely lobulated fibrofatty soft tissue. On section, two gray-white tumor nodules are identified, 2.0 and 3.0 cm in greatest dimension. A section is submitted for frozen section with the residual entirely resubmitted for permanent section in cassette A1 labeled [REDACTED]. Additional representative sections are submitted in cassettes A2-3. Additionally, a yellow cassette is submitted for genomics research labeled [REDACTED].

Container B is additionally labeled "#2" and contains an 18.0 x 8.5 x 3.5 cm, yellow-tan, finely lobulated fibrofatty soft tissue consistent with omentum. Sectioning reveals gray-white tumor up to 6.0 cm in greatest dimension. Representative sections are submitted in cassettes B1-4 labeled [REDACTED].

Container C is additionally labeled "uterus, right tube and ovary" and contains a 41.6 gm supracervical hysterectomy specimen comprised of uterine corpus (5.5 cm in length by 3.5 x 3.5 cm), right fallopian tube (6.0 cm in length and ranging from 0.5 to 1.0 cm) and right ovary (3.0 x 1.5 x 1.3 cm). The uterine corpus is surfaced by pink-tan, shaggy serosa. The parametrial soft tissue is inked and taken en face. The endometrium is pink-tan and lush with an average thickness of 0.3 cm. Discrete invasive lesions are not identified. The surrounding myometrium is pink-tan and fibrous with an average thickness of 1.1 cm. No myometrial nodules or lesions are identified. The ovary is sectioned to reveal a yellow-tan fibrous cut surface with a gray-white corpus albicans and a 0.6 cm cystic ovary. The cyst features a gray-white papillary excrescence and contains clear, watery fluid. Representative sections are submitted in cassettes C1-16 labeled [REDACTED] designated as follows: 1 right parametrium, en face; 2 left parametrium, en face; 3 anterior lower uterine segment; 4 posterior lower uterine segment; 5-6 full thickness anterior endomyometrium; 7 remainder of anterior endometrium; 8-9 full thickness posterior endomyometrium; 10-11 remainder of posterior endometrium; 12 fallopian tube; 13-16 ovary, entirely.

INTRA-OPERATIVE CONSULTATION:

FROZEN SECTION DIAGNOSIS: Part A - Metastatic adenocarcinoma per Dr [REDACTED]

Source: NCI Genomic Data Commons file d40816b0-7228-4f71-af80-08e92c1633b4 (TCGA-AJ-A23N.38EB6233-9777-4640-A896-26D16A9DBD8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).